Gene-level copy-number profile of tumor specimen TCGA-2G-AAKF-01A from TCGA case TCGA-2G-AAKF, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 45.4 years (16,593 days).
Specimen TCGA-2G-AAKF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4c18a15b-3297-453c-8863-f53da92b11da.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-2G-AAKF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,721 have no estimate.
https://portal.gdc.cancer.gov/files/12a47d20-ff18-44ea-8fcb-5b59051596d1

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 536; copy number 2: 18,474; copy number 3: 22,079; copy number 4: 10,831; copy number 5: 6,093; copy number 6: 47; copy number 7: 7; copy number 8: 827.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:39,734,670–39,741,193, 2 genes: RAB28P1, RBPJP5.
- chr10:87,201,647–87,370,695, 6 genes (within-gene range 0–1): NUTM2A-AS1, AL157893.2, AL157893.1, NUTM2A, LINC00863, NUTM2D.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 834 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:40,346,144–40,358,682, 3 genes, copy number 7: CNN2P2, GXYLT1P3, AL591471.1.
- chr12:66,767–34,249,958, 831 genes, copy number 7–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 20. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
